Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A82B, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A82B-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: A mass is located in right feet skin, with 5x4x2cm, firm, brown, black-gray surface

Microscopic Description: Epidermis is necrotic, ulcerated. Tumor is composed of spindle or oval tumor cells with quite scant cytoplasm. Sometime the cytoplasm contains finely divided melanin pigment granulae. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are present. Tumor cells invade into fat tissue.

Diagnosis Details: Malignant melanoma

Breslow tumor thickness: 20mm

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin, foot

Pen TSS, non-glabrous skin affected.

Tumor size: 5 x 4 x 2 cm

Tumor features: Ulcerated, Pigmented, Necrotic

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 2/9 positive for metastasis (Right inguinal and pelvic lymph node 2/9)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Right foot, Breslow tumor thickness: 20mm

Comments: None

*ICD-O-3
Melanoma, malignant NOS
8720/3
Site R foot, skin C44.7
JW 10/30/13*

BCE

Diagnosis Discrepancy	hwl 10/23/13	☒
Local/Syncytic Primary Malignancy		☒
Date Re-reviewed	10/10/13	

Source: NCI Genomic Data Commons file 9d561ee1-87b7-4692-a892-38d1cfc39724 (TCGA-EB-A82B.23E186C6-739C-4EF1-8788-79AA89C6E87A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).